Somatic mutation profile of tumor specimen TCGA-BG-A0MO-01A (aliquot TCGA-BG-A0MO-01A-11W-A062-09) from TCGA case TCGA-BG-A0MO, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 63.8 years (23,287 days).
Specimen TCGA-BG-A0MO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c73615e0-ab1a-4d41-96d8-3ada91d47e7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0MO-10A (Blood Derived Normal), aliquot TCGA-BG-A0MO-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/424cb973-3c8d-4a25-aafb-b75ccfbf2308

The open-access MAF lists 47 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 11, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 2/8 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 49/95 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- ACAD11 | c.1390G>C p.D464H | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53900792; called by muse, mutect2, varscan2
- AKAP11 | c.5175C>A p.N1725K | Missense Mutation (SNP) | VAF 78/214 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV50292897; called by muse, mutect2, varscan2
- CCDC110 | c.115+2T>G p.X39_splice | Splice Site (SNP) | VAF 19/38 reads (50%) | catalogued as COSV56873084; called by muse, mutect2, varscan2
- CCNJ | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV56442134, COSV56444382; called by muse, mutect2, varscan2
- CHD6 | c.4164G>T p.W1388C | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64693944; called by muse, mutect2, varscan2
- CPNE6 | c.1357C>G p.R453G | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53746217; called by muse, mutect2, varscan2
- DCAF4L2 | c.308C>A p.T103N | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60477009; called by muse, mutect2, varscan2
- DPYSL4 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as rs368276800; called by muse, mutect2, varscan2
- FAM135B | c.4087C>T p.R1363* | Nonsense Mutation (SNP) | VAF 94/210 reads (45%) | catalogued as rs758974242, COSV52734447; called by muse, mutect2, varscan2
- FAM9A | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.966); catalogued as COSV66813706; called by muse, mutect2, varscan2
- FCRL3 | c.567T>G p.F189L | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV63844563; called by muse, mutect2, varscan2
- HIBCH | c.549C>G p.F183L | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV62892991; called by muse, mutect2, varscan2
- HID1 | c.356G>T p.W119L | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV59352257; called by muse, mutect2, varscan2
- KCNA4 | c.1336A>G p.I446V | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as COSV60255579; called by muse, mutect2, varscan2
- LRP2 | c.10027C>T p.R3343C | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs140572511; called by muse, mutect2, varscan2
- MAGED1 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.029); catalogued as rs373153783, COSV58516678; called by muse, mutect2
- MTOR | c.6037A>G p.S2013G | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63869730; called by muse, mutect2, varscan2
- PCNX2 | c.3886C>A p.P1296T | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50870842; called by muse, mutect2, varscan2
- PPIA | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.305); catalogued as COSV63534296; called by muse, mutect2, varscan2
- PRPF8 | c.5624A>G p.H1875R | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV59261977, COSV59266339; called by muse, mutect2, varscan2
- RUNX1T1 | c.1402G>A p.V468M (on ENST00000265814 / NM_001198628.1; = p.V441M on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV56143586; called by muse, mutect2, varscan2
- RYR2 | c.14566G>A p.V4856I | Missense Mutation (SNP) | VAF 92/317 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV100773355, COSV63710173; called by muse, mutect2, varscan2
- SLC12A5 | c.161G>A p.S54N (on ENST00000454036 / NM_001134771.2; = p.S31N on NM_020708.5) | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV54800932; called by muse, mutect2, varscan2
- SMG7 | c.2216C>G p.P739R | Missense Mutation (SNP) | VAF 163/564 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as COSV61630921, COSV61633952; called by muse, mutect2, varscan2
- SYCP2 | c.880C>A p.Q294K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV62772054; called by muse, mutect2, varscan2
- TAF1 | c.3638G>A p.R1213Q (on ENST00000373790 / NM_138923.4; = p.R1234Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/297 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV52123626; called by muse, mutect2
- THSD1 | c.665T>G p.L222R | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.235); catalogued as COSV51631353; called by muse, mutect2, varscan2
- TMEM150A | c.532C>T p.R178* (on ENST00000334462 / NM_001031738.3; = p.R125* on NM_153342.3) | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as rs751247738, COSV57818274; called by muse, mutect2, varscan2
- ZNF236 | c.2605A>G p.S869G | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV53496365; called by muse, mutect2, varscan2
- ZNF800 | c.1984G>T p.A662S | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV56179381; called by muse, mutect2, varscan2
- AHNAK | c.16493del p.K5498Sfs*7 | Frame Shift Del (DEL) | VAF 105/270 reads (39%) | called by mutect2, pindel, varscan2
- CTCF | c.1896del p.I632Mfs*10 | Frame Shift Del (DEL) | VAF 35/83 reads (42%) | called by mutect2, pindel, varscan2
- ZMYM2 | c.2853del p.T952Qfs*2 | Frame Shift Del (DEL) | VAF 44/119 reads (37%) | called by mutect2, pindel, varscan2
- AQP12B | c.72C>A p.A24= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV68184408; called by muse, mutect2, varscan2
- DSP | c.1614C>T p.N538= | Silent (SNP) | VAF 69/158 reads (44%) | catalogued as COSV65795389; called by muse, mutect2, varscan2
- FRMPD4 | c.387C>T p.S129= | Silent (SNP) | VAF 98/180 reads (54%) | catalogued as rs765760989, COSV66222129; called by muse, mutect2, varscan2
- GFRA3 | c.633C>T p.H211= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs915081765, COSV51231085; called by muse, mutect2, varscan2
- GLCCI1 | c.1245C>T p.F415= | Silent (SNP) | VAF 67/146 reads (46%) | catalogued as COSV56204792; called by muse, mutect2, varscan2
- MUC4 | c.13677C>T p.L4559= (on ENST00000463781 / NM_018406.7; = p.L323= on NM_004532.6) | Silent (SNP) | VAF 33/52 reads (63%) | catalogued as rs142880712; called by muse, mutect2, varscan2
- NOD1 | c.2838T>C p.D946= | Silent (SNP) | VAF 63/175 reads (36%) | catalogued as COSV56114599; called by muse, mutect2, varscan2
- PCDH15 | c.4335G>A p.A1445= | Silent (SNP) | VAF 28/48 reads (58%) | catalogued as rs570557379, COSV57382499; called by muse, mutect2, varscan2
- POGZ | c.1953A>G p.K651= | Silent (SNP) | VAF 731/1222 reads (60%) | catalogued as COSV55041366; called by muse, mutect2, varscan2
- SNRNP200 | c.964C>A p.R322= | Silent (SNP) | VAF 14/182 reads (8%) | catalogued as COSV60493989; called by muse, mutect2
- TNPO2 | c.1071C>T p.D357= | Silent (SNP) | VAF 57/109 reads (52%) | catalogued as rs770308688, COSV63507520; called by muse, mutect2, varscan2
- FMN1 | c.2044-2080C>G | Intron (SNP) | VAF 82/208 reads (39%) | catalogued as COSV57931981; called by muse, mutect2
